Somatic mutation profile of tumor specimen TARGET-40-NAAWEZ-01A (aliquot TARGET-40-NAAWEZ-01A-01D) from TARGET case TARGET-40-NAAWEZ, project TARGET-OS (Osteosarcoma). Sex at birth: female; Primary diagnosis: Osteosarcoma, NOS; Age at diagnosis: 19.0 years (6,935 days).
Specimen TARGET-40-NAAWEZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4d9e5236-2158-4b22-9044-98042c204802.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAWEZ-10A (Blood Derived Normal), aliquot TARGET-40-NAAWEZ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0999d4ce-f0de-45a1-8858-72765271f38f

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IARS1 | c.1331G>A p.R444Q | Missense Mutation (SNP) | VAF 103/171 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200389880; called by muse, mutect2, varscan2
- NAV3 | c.6585A>C p.K2195N (on ENST00000397909 / NM_001024383.2; = p.K2173N on NM_014903.6) | Missense Mutation (SNP) | VAF 36/56 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57069057; called by muse, varscan2
- NBAS | c.6162C>A p.D2054E | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs1238119569; called by muse, mutect2, varscan2
- PTPRH | c.529G>A p.G177R | Missense Mutation (SNP) | VAF 15/428 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.397); catalogued as rs1250953238, COSV54745895; called by muse, mutect2
- CAMTA1 | c.1739C>A p.T580N | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GPHN | c.1120G>C p.D374H (on ENST00000315266 / NM_001377519.1; = p.D407H on NM_020806.5) | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- MUC16 | c.6226G>T p.G2076C | Missense Mutation (SNP) | VAF 28/271 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PP2D1 | c.450T>G p.F150L | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- NTRK3 | c.2382C>G p.V794= (on ENST00000360948 / NM_001012338.2; = p.V780= on NM_002530.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/199 reads (5%) | catalogued as COSV100713325; called by muse, mutect2
- TERT | c.1896G>A p.P632= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as rs140056333; ClinVar: likely benign; called by muse, mutect2, varscan2
- IGFN1 | c.1242-1192G>T | Intron (SNP) | VAF 15/102 reads (15%) | called by muse, mutect2, varscan2
